Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040025-09A.2 (aliquot TARGET-15-SJMPAL040025-09A.2-01D) from TARGET case TARGET-15-SJMPAL040025, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,319 days).
Specimen TARGET-15-SJMPAL040025-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b0e5f8a-671e-4477-bdca-2bbc246c9a0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040025-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040025-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/568df869-c0a7-4d7e-b088-a1eafd7f2d5a

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM170B | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs1357217182, COSV61253558; called by muse, mutect2, varscan2
- PIK3R3 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1296227284, COSV53109967; called by muse, mutect2
- TECTA | c.5669G>A p.R1890H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs371520052; called by muse, mutect2, varscan2
- HGS | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506994 TGTAT>GGGGGGAG | Missense Mutation (INS) | VAF 28/73 reads (38%) | called by muse*, pindel
- TNFRSF25 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10824C>A p.S3608R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZMIZ1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TNFRSF25 | c.1155G>A p.Q385= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- TNFSF10 | c.537A>G p.K179= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- ZNF831 | c.1026C>G p.T342= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs939365835, COSV100926340; called by muse, mutect2, varscan2
- TMEM121B | chr22:17122031 C>A | 5'Flank (SNP) | VAF 3/24 reads (13%) | catalogued as rs866910587; called by muse, mutect2
